Gene-level copy-number profile of tumor specimen TCGA-31-1944-01A from TCGA case TCGA-31-1944, project TCGA-OV (Ovarian Serous Cystadenocarcinoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Serous cystadenocarcinoma, NOS; Tissue or organ of origin: Ovary; FIGO stage: Stage IIIC; Tumor grade: G3; Age at diagnosis: 47.1 years (17,207 days).
Specimen TCGA-31-1944-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-OV.26cb4901-7bc2-4f43-8c4e-fb2d1f3b48ff.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-31-1944-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 807 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/33e82bad-a4a7-4c9a-bce9-8fa0baa231e7

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 0: 1; copy number 1: 17,039; copy number 2: 34,757; copy number 3: 6,503; copy number 4: 947; copy number 5: 567; copy number 6: 2.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, sample TCGA-31-1944-01): tumor purity 0.79, ploidy 1.93, whole-genome doublings 0 (call status: legacy_call).

Homozygous deletions (total copy number 0; autosomes only): 1 gene in 1 contiguous region (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr8:3,700,492–3,700,628, 1 gene: RNA5SP251.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 569 genes in 3 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr8:139,727,725–140,458,579, 1 gene, copy number 6 (within-gene range 4–6): TRAPPC9.
- chr8:140,094,894–140,100,543, 1 gene, copy number 6: PEG13.
- chr20:42,685,404–64,313,132, 567 genes, copy number 5 (broad region; genes not listed).

Autosomal genes at a single copy (total copy number 1): 17,039. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
